Somatic mutation profile of tumor specimen 0DUVTS from CCDI case PBCLUV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0DUVTS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d72c474-27d4-4148-af94-93f2e7fef7a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUVT6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28d30a76-5205-4aae-8d55-4109a9a54c3b

The open-access MAF lists 48 somatic variants for this specimen: 27 protein-altering or splice-affecting, 14 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 14, Intron 3, 5'UTR 1, 5'Flank 1, Nonsense Mutation 1, 3'UTR 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 278/778 reads (36%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 256/576 reads (44%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.379T>A p.S127T | Missense Mutation (SNP) | VAF 327/772 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52667433, COSV52678360, COSV52751962; called by muse, mutect2, varscan2
- ABCB11 | c.2107C>T p.L703F | Missense Mutation (SNP) | VAF 242/1345 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.634); catalogued as rs750821906; called by muse, mutect2, varscan2
- ATRX | c.4215-1G>T p.X1405_splice | Splice Site (SNP) | VAF 230/240 reads (96%) | catalogued as COSV64878882; called by muse, mutect2, varscan2
- EPPK1 | c.9818C>T p.T3273M | Missense Mutation (SNP) | VAF 116/693 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1390480177; called by muse, mutect2, varscan2
- MASP1 | c.506G>T p.R169L | Missense Mutation (SNP) | VAF 350/759 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV51457449, COSV51460255; called by muse, mutect2, varscan2
- MCIDAS | c.186T>A p.D62E | Missense Mutation (SNP) | VAF 90/399 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.241); catalogued as rs568641089; called by muse, mutect2, varscan2
- MFSD2A | c.379C>T p.R127C (on ENST00000372809 / NM_001136493.3; = p.R114C on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 148/801 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs556985300, COSV100861610; called by muse, mutect2, varscan2
- PGAP1 | c.104A>G p.N35S | Missense Mutation (SNP) | VAF 306/761 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); catalogued as rs149238260; called by muse, mutect2, varscan2
- SDK2 | c.2983C>T p.P995S | Missense Mutation (SNP) | VAF 366/834 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.059); catalogued as rs983205823, COSV101169141; called by mutect2, varscan2
- TOGARAM2 | c.2716C>A p.L906M | Missense Mutation (SNP) | VAF 227/514 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs376580582; called by muse, mutect2, varscan2
- URB2 | c.3875G>A p.R1292H | Missense Mutation (SNP) | VAF 253/618 reads (41%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.52); catalogued as rs747572919, COSV99270463; called by muse, mutect2, varscan2
- AC100868.1 | c.1043G>A p.C348Y | Missense Mutation (SNP) | VAF 222/612 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CBLC | c.518C>A p.A173D | Missense Mutation (SNP) | VAF 206/443 reads (47%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- CLCN5 | c.2017A>T p.T673S | Missense Mutation (SNP) | VAF 231/258 reads (90%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCLRE1C | c.877T>C p.W293R (on ENST00000378278 / NM_001350965.2; = p.W178R on NM_022487.4) | Missense Mutation (SNP) | VAF 708/1356 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- FAT4 | c.2574G>T p.E858D | Missense Mutation (SNP) | VAF 215/482 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- FCGBP | c.4483G>T p.G1495C | Missense Mutation (SNP) | VAF 182/493 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FOXC1 | c.863C>A p.A288E | Missense Mutation (SNP) | VAF 90/168 reads (54%) | SIFT tolerated (0.31); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- FOXRED1 | c.1187C>A p.P396Q | Missense Mutation (SNP) | VAF 111/650 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- GUCY1B1 | c.378A>C p.E126D | Missense Mutation (SNP) | VAF 405/915 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IL23A | c.502A>T p.S168C | Missense Mutation (SNP) | VAF 161/723 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- LRP2 | c.8404G>T p.G2802C | Missense Mutation (SNP) | VAF 320/846 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC22 | c.3980C>A p.T1327K | Missense Mutation (SNP) | VAF 334/758 reads (44%) | SIFT deleterious (0.05); called by muse, mutect2, varscan2
- SMPDL3A | c.338C>G p.P113R | Missense Mutation (SNP) | VAF 253/546 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TUBAL3 | c.773A>G p.D258G | Missense Mutation (SNP) | VAF 381/827 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ASPHD2 | c.123C>T p.G41= | Silent (SNP) | VAF 283/1046 reads (27%) | called by muse, mutect2, varscan2
- ATF5 | c.714C>T p.G238= | Silent (SNP) | VAF 151/347 reads (44%) | catalogued as rs140494656; called by muse, mutect2, varscan2
- COPG2 | c.1572A>T p.V524= | Silent (SNP) | VAF 364/908 reads (40%) | called by muse, mutect2, varscan2
- CPS1 | c.1716T>C p.D572= | Silent (SNP) | VAF 235/1085 reads (22%) | catalogued as rs764231738; ClinVar: likely benign; called by muse, mutect2, varscan2
- HELZ | c.5628G>T p.A1876= | Silent (SNP) | VAF 101/636 reads (16%) | catalogued as rs745477812; called by muse, mutect2, varscan2
- HEPH | c.3354C>A p.T1118= (on ENST00000343002; = p.T851= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 428/456 reads (94%) | called by muse, mutect2, varscan2
- LAMC1 | c.4089T>G p.A1363= | Silent (SNP) | VAF 166/829 reads (20%) | called by muse, mutect2, varscan2
- MAP3K19 | c.3954C>A p.L1318= | Silent (SNP) | VAF 256/666 reads (38%) | called by muse, mutect2, varscan2
- MUC16 | c.38220G>A p.K12740= | Silent (SNP) | VAF 339/861 reads (39%) | called by muse, mutect2, varscan2
- MYO18B | c.463T>C p.L155= | Silent (SNP) | VAF 240/547 reads (44%) | called by muse, mutect2, varscan2
- OR2L5 | c.492T>C p.R164= | Silent (SNP) | VAF 381/874 reads (44%) | catalogued as rs1407594424; called by muse, mutect2, varscan2
- RAD54L | c.1626C>A p.R542= | Silent (SNP) | VAF 136/742 reads (18%) | called by muse, mutect2, varscan2
- THSD7A | c.1845G>A p.L615= | Silent (SNP) | VAF 246/588 reads (42%) | called by muse, mutect2, varscan2
- TRPC4AP | c.147G>T p.R49= | Silent (SNP) | VAF 168/388 reads (43%) | called by muse, mutect2, varscan2
- CLUH | c.3443+51G>C | Intron (SNP) | VAF 53/111 reads (48%) | called by muse, mutect2, varscan2
- CNTNAP3 | c.3355-18T>C | Intron (SNP) | VAF 89/178 reads (50%) | catalogued as rs1228568675; called by muse, mutect2, varscan2
- COL4A3 | c.387+13C>G | Intron (SNP) | VAF 384/863 reads (44%) | called by muse, mutect2, varscan2
- FOXK2 | c.*65G>A | 3'UTR (SNP) | VAF 69/166 reads (42%) | catalogued as COSV100082210; called by muse, mutect2, varscan2
- PAPLN | c.-12C>T | 5'UTR (SNP) | VAF 168/189 reads (89%) | called by muse, mutect2, varscan2
- TLCD3A | chr17:732571 T>C | 5'Flank (SNP) | VAF 46/108 reads (43%) | catalogued as rs1430259666; called by muse, mutect2, varscan2
- TOMM40P2 | n.798A>T | RNA (SNP) | VAF 62/833 reads (7%) | called by muse, mutect2
